Somatic mutation profile of tumor specimen BA2588D (aliquot aq-BA2588D) from BEATAML1.0 case 2441, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.2 years (21,637 days).
Specimen BA2588D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f8af40d-cd35-4eb5-8b8e-a739bebff85f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2941D (Solid Tissue Normal), aliquot aq-BA2941D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eec617bd-6078-42d2-83ea-e299e00c60e4

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPN11 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as rs397516801; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD300E | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV60791660; called by muse, mutect2, varscan2
- CNTNAP5 | c.3700C>T p.R1234* | Nonsense Mutation (SNP) | VAF 58/164 reads (35%) | catalogued as rs982218609, COSV70474001, COSV70477179; called by muse, mutect2, varscan2
- DPF2 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52888447, COSV52891275; called by muse, mutect2, varscan2
- DPY19L2 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs765434660; called by muse, mutect2, varscan2
- GRIK4 | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV101483370; called by muse, mutect2
- PKNOX1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 103/282 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs141136324; called by muse, mutect2, varscan2
- TGFBR3 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99283134; called by muse, mutect2, varscan2
- ZNFX1 | c.5506G>T p.V1836F | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1390144007; called by muse, mutect2
- HNRNPH1 | c.1301-5T>G | Splice Region (SNP) | VAF 58/161 reads (36%) | called by muse, mutect2, varscan2
- ILF3 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MBTPS1 | c.2085G>T p.M695I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SEZ6L | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- SIK2 | c.1807C>A p.Q603K | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.297); called by muse, mutect2
- SLC38A7 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- LRRTM4 | c.1449G>A p.E483= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs1268625744, COSV69142065; called by muse, mutect2, varscan2
- HSPA1B | c.-4C>A | 5'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- TALDO1 | c.98-27T>C | Intron (SNP) | VAF 78/201 reads (39%) | catalogued as rs1239624312; called by muse, mutect2, varscan2
